Somatic mutation profile of tumor specimen TCGA-AA-3678-01A (aliquot TCGA-AA-3678-01A-01W-0900-09) from TCGA case TCGA-AA-3678, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage III; Age at diagnosis: 60.8 years (22,219 days).
Specimen TCGA-AA-3678-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7087674f-e95e-438d-80e6-17aad235920e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3678-10A (Blood Derived Normal), aliquot TCGA-AA-3678-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e114d061-9c6a-41a5-b734-cf527e0311bb

The open-access MAF lists 78 somatic variants for this specimen: 63 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 14, Splice Site 2, Splice Region 2, Frame Shift Del 2, Frame Shift Ins 2, Nonsense Mutation 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.7274del p.G2425Vfs*15 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | catalogued as rs1565527283; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACKR2 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs780739221, COSV56177735; called by muse, mutect2, varscan2
- ADAMTS14 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs369181052; called by muse, mutect2, varscan2
- ADGRG4 | c.5225C>G p.S1742C | Missense Mutation (SNP) | VAF 279/551 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV54955025; called by muse, mutect2, varscan2
- ADGRG4 | c.6425T>G p.V2142G | Missense Mutation (SNP) | VAF 79/239 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV54955041; called by muse, mutect2, varscan2
- APC | c.3932_3933del p.I1311Rfs*3 | Frame Shift Del (DEL) | VAF 48/131 reads (37%) | catalogued as COSV57341445; called by mutect2, pindel, varscan2
- AQP9 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 72/140 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs536480649, COSV54968564, COSV99582571; called by muse, mutect2, varscan2
- ATN1 | c.712G>C p.G238R | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as rs1565565764, COSV63110925; called by muse, mutect2, varscan2
- ATP7A | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 107/285 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs377714939, COSV58445652; ClinVar: likely benign; called by muse, mutect2, varscan2
- C12orf54 | c.134A>T p.Q45L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV58360261; called by muse, mutect2, varscan2
- CACNA1A | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs772354342, COSV64195160, COSV64196834; called by muse, mutect2, varscan2
- CDC25C | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60399215; called by muse, mutect2, varscan2
- CDON | c.1559T>C p.F520S | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV54997505; called by muse, mutect2, varscan2
- CERS5 | c.305A>T p.Y102F | Missense Mutation (SNP) | VAF 13/384 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as COSV100451968; called by muse, mutect2
- COL24A1 | c.5071G>A p.E1691K | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as rs1432062715, COSV65306533; called by muse, mutect2
- DAB2 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs201380557, COSV57912080, COSV57914097; called by muse, mutect2, varscan2
- DHX38 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as rs373210227; called by muse, mutect2, varscan2
- DNAH11 | c.4172C>A p.T1391K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV60953759; called by muse, mutect2, varscan2
- DSCAM | c.2696G>A p.R899H | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs977050001, COSV68025859; called by muse, mutect2, varscan2
- FAM47A | c.2042C>T p.T681M | Missense Mutation (SNP) | VAF 129/365 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs770609384, COSV60495030; called by muse, mutect2, varscan2
- FANCA | c.3754G>A p.E1252K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs766875357, CM125192, COSV57067847; called by muse, mutect2, varscan2
- FBLN1 | c.1721C>T p.T574M | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs200901023, COSV59937578; called by muse, mutect2
- GRIA4 | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439286427, COSV56887547; called by muse, mutect2, varscan2
- HEATR5B | c.4544A>T p.E1515V | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51852235; called by muse, mutect2, varscan2
- IFRD2 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782161246, COSV57113565; called by muse, mutect2, varscan2
- ITPA | c.562T>G p.Y188D | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV66261732; called by muse, mutect2, varscan2
- ITPRIP | c.1438G>A p.G480S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750228977, COSV53391398; called by muse, mutect2, varscan2
- LARGE1 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.178); catalogued as rs139853494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LEMD3 | c.2695C>T p.R899C | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs201280850, COSV57650147; called by muse, mutect2, varscan2
- MUC21 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs1286522531, COSV66220729; called by muse, mutect2, varscan2
- MYBL2 | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV53829010; called by muse, mutect2, varscan2
- NCKAP5 | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747843825, COSV58441127; called by muse, mutect2, varscan2
- NR2F2 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV67683437; called by muse, mutect2, varscan2
- PCDHGA7 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); catalogued as rs1445366017, COSV53934427; called by muse, mutect2, varscan2
- PKHD1 | c.5418_5420del p.E1806del | In Frame Del (DEL) | VAF 46/184 reads (25%) | catalogued as rs1554194551; called by pindel, varscan2
- POLE | c.5254G>A p.D1752N | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs1335665224, COSV57679450; called by muse, mutect2, varscan2
- PSME4 | c.5084A>T p.E1695V | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.489); catalogued as COSV66364684; called by muse, mutect2, varscan2
- REG1B | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV59304482, COSV59307204, COSV59307463; called by muse, mutect2, varscan2
- RHOBTB3 | c.1707T>G p.F569L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV66101938; called by muse, mutect2, varscan2
- RIPPLY2 | c.377G>C p.C126S | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as COSV63746456; called by muse, mutect2, varscan2
- RLIM | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.996); catalogued as rs1214812674, COSV60325092; called by muse, mutect2, varscan2
- SALL1 | c.2795C>A p.S932Y | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV51756726; called by muse, mutect2, varscan2
- SCLY | c.510G>A p.A170= (on ENST00000651534; = p.A162= on NM_016510.7) | Splice Region (SNP) | VAF 8/46 reads (17%) | catalogued as rs767965636, COSV54541167; called by muse, mutect2
- SCN11A | c.3865G>A p.V1289I | Missense Mutation (SNP) | VAF 83/223 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as rs536925812, COSV56569504; ClinVar: likely benign; called by muse, mutect2, varscan2
- SETD2 | c.6872C>T p.S2291F | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100338736; called by muse, mutect2, varscan2
- SHISA5 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1237761044, COSV56499661; called by muse, mutect2, varscan2
- SLC35F1 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 108/302 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764902544, COSV64502570; called by muse, mutect2, varscan2
- SLC6A15 | c.1684G>A p.G562S | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1320673855, COSV57023062, COSV57025591; called by muse, mutect2, varscan2
- SOAT1 | c.497+2T>C p.X166_splice | Splice Site (SNP) | VAF 39/321 reads (12%) | catalogued as COSV62653947; called by muse, mutect2, varscan2
- STAG1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs774614550, COSV52604457; called by muse, mutect2, varscan2
- STBD1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV52953784; called by muse, mutect2, varscan2
- TENM2 | c.1465G>A p.A489T (on ENST00000518659 / NM_001122679.2; = p.A257T on NM_001080428.3) | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs764193780, COSV69127008; called by muse, mutect2, varscan2
- TRIM13 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.35); catalogued as COSV53951075; called by muse, mutect2
- TRIP4 | c.272-1del p.X91_splice | Splice Site (DEL) | VAF 29/95 reads (31%) | catalogued as COSV56030186; called by mutect2, pindel, varscan2
- TRRAP | c.5521G>T p.E1841* (on ENST00000359863 / NM_001244580.1; = p.E1823* on NM_003496.3) | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV62843519; called by muse, mutect2, varscan2
- TTBK1 | c.3007dup p.R1003Pfs*33 | Frame Shift Ins (INS) | VAF 6/39 reads (15%) | catalogued as rs756405350; called by mutect2, pindel
- UXT | c.249C>G p.V83= | Splice Region (SNP) | VAF 24/62 reads (39%) | catalogued as COSV60039396; called by muse, mutect2, varscan2
- WDSUB1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1271512935, COSV63067259; called by muse, mutect2, varscan2
- ZDBF2 | c.6418C>T p.L2140F | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV65625209; called by muse, mutect2, varscan2
- ZNF334 | c.1421C>A p.S474* | Nonsense Mutation (SNP) | VAF 143/439 reads (33%) | catalogued as COSV61618529; called by muse, mutect2, varscan2
- ZNF423 | c.1216C>T p.R406W (on ENST00000563137 / NM_001379286.1; = p.R398W on NM_015069.4) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs368847069, COSV99281009; called by muse, mutect2, varscan2
- ZNF430 | c.501G>C p.Q167H | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV55109439; called by muse, mutect2, varscan2
- ATM | c.4823_4824dup p.T1609* | Frame Shift Ins (INS) | VAF 28/143 reads (20%) | called by mutect2, pindel, varscan2
- AMIGO2 | c.1329G>A p.S443= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs778696499, COSV56974123; called by muse, mutect2, varscan2
- CCKBR | c.756C>T p.D252= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs747685589, COSV58100637; called by muse, mutect2, varscan2
- FATE1 | c.366G>A p.A122= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as rs139813476, COSV64848857; called by muse, mutect2, varscan2
- FTO | c.558C>T p.N186= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as rs45492996, COSV67111462; called by muse, mutect2, varscan2
- H2BC8 | c.237C>T p.S79= | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as rs1422338671, COSV55126700; called by muse, mutect2, varscan2
- HBD | c.255T>G p.T85= | Silent (SNP) | VAF 28/230 reads (12%) | catalogued as COSV53082500, COSV53083850; called by muse, mutect2
- PCDHA8 | c.1689G>A p.P563= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV65327882; called by muse, mutect2, varscan2
- PPEF1 | c.930A>C p.I310= | Silent (SNP) | VAF 85/262 reads (32%) | catalogued as COSV62995616, COSV62995639; called by muse, mutect2, varscan2
- S1PR3 | c.972C>T p.R324= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as rs201820975; called by muse, mutect2, varscan2
- SDC4 | c.153C>T p.P51= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs750999803, COSV101023430, COSV65595392; called by muse, mutect2, varscan2
- SLC4A11 | c.1308G>A p.A436= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs764539635, COSV66261737; called by muse, mutect2, varscan2
- SLIT3 | c.1797C>T p.R599= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs559665628, COSV60606079; called by muse, mutect2, varscan2
- TACR3 | c.243G>A p.P81= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as rs936251368, COSV59200930; called by muse, mutect2, varscan2
- TLR9 | c.756C>T p.G252= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs200139837, COSV62345547; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501501 del TTG | 5'Flank (DEL) | VAF 7/33 reads (21%) | catalogued as rs774307086; called by mutect2, pindel, varscan2
